CCDI case PBBNLA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/872a1552-b467-4454-8a71-3bf9933a0b38

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,917 days).

Biospecimens (3 samples)
- Sample 0DDHTQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDHU3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDHU4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
